Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A3NI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A3NI-01A (Primary Tumor).

[page 1 of 4]
Collection Date:
Hospital of Origin:
Copy to:

QC Pathologist:

Reviewer (initials)		

FINAL PATHOLOGIC DIAGNOSIS:

A. Ovary and fallopian tube, right, salpingo-oophorectomy:
Ovary, no pathologic change.

Fallopian tube, lumen dilatation consistent with
hematosalpinx.

Negative for neoplasm.

B. Ovary and fallopian tube, left, salpingo-oophorectomy:

Ovary, no pathologic change, corpus luteum present.

Fallopian tube, no pathologic change.

Paratubal cyst.

C. Uterus, radical hysterectomy:

Cervix, invasive squamous cell carcinoma, keratinizing type.
Grade II.

Tumor size: Approximately 25 x 22 mm.

Invasion depth 11 mm (total cervical wall thickness of 19
mm).

Lymphovascular space invasion present.

Surgical margins free of tumor (vaginal and parametrial).

Vaginal mucosa, no pathologic change.

Endometrium, secretory pattern.

Endometrial polyp, functional type.

Myometrium, intramural leiomyomata.

Parametrium, lymph node with no pathologic change, negative
for neoplasm (0/1).

D. Lymph nodes, left external iliac, dissection:

Metastatic squamous cell carcinoma involving two of seven
nodes examined (2/7).

E. Lymph nodes, left obturator, dissection:

Negative for neoplasm, five nodes examined (0/5).

F. Lymph nodes, left common iliac and lower aortic,
dissection:

Negative for neoplasm, four nodes examined (0/4).

G. Lymph nodes, right external iliac, dissection:

Negative for neoplasm, three nodes examined (0/3).

H. Lymph nodes, right obturator, dissection:

Negative for neoplasm, five nodes examined (0/5).

I. Lymph nodes, right common iliac and lower aortic,
dissection:

Negative for neoplasm, four nodes examined (0/4).

1CD-0-3

carcinoma, squamous cell, keratinizing, NOS 8071/3

Site: cervix, NOS C53.9

hw
1/7/12

[page 2 of 4]
J. Omentum, omentectomy:
Negative for neoplasm.
Staging (AJCC 2010): pT1b1,N1 (FIGO: IIB)

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right ovary and tube
- B. Left ovary and tube
- C. Radical hysterectomy
- D. Left external iliac lymph node
- E. Left obturator lymph node
- F. Left common iliac and lower aortic lymph nodes
- G. Right external iliac lymph node
- H. Right obturator lymph node
- I. Right common iliac and lower aortic lymph nodes
- J. Omentum

CODES:

88307
88307
88307
88307
88307
88307
88307
88307
88307
88307

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

GROSS DESCRIPTION:

The specimen is received in ten formalin-filled containers labeled with the patient's name

A. Container A is additionally labeled "right ovary and tube," and contains a 3.6 gm, 2.5 x 2.5 x 1.4 cm, yellow-tan lobulated ovary received with attached paraovarian soft tissue and segment of fallopian tube, 3.5 cm in length and ranging from 0.7 up to 1.0 cm in diameter. Sections through the tube reveal a dilated lumen containing red-brown, hemorrhagic fluid. The ovary is sectioned to reveal a hemorrhagic corpus luteum. The remainder of the cut surface is tan-gray and fibrous with multiple gray-white corpora albicantia.

B. Container B is additionally labeled "left ovary and tube," and contains a 6.6 gm, 3.5 x 2.8 x 1.8 cm, yellow-tan lobulated ovary received with attached paraovarian soft tissue and segment of fimbriated fallopian

[page 3 of 4]
tube. The tube has been previously interrupted and when reconstructed is 5.0 cm in length and ranges from 0.7 to 0.9 cm in diameter. A 0.3 cm, uniloculated paratubal cyst is present at the proximal end. It features a smooth inner lining and contains clear, watery fluid. The ovary is sectioned to reveal a tan-pink fibrous cut surface with multiple gray-white corpora albicantia and a hemorrhagic corpus luteum. A 0.6 cm uniloculated subcortical cyst is present. It features a smooth inner lining and contains clear, watery fluid. Representative sections are submitted in cassettes B1-3, labeled _____ designated as follows: 1, cross sections of fallopian tube; 2-3, ovary. C. Container C is additionally labeled "radical hysterectomy" and consists of a 117.2 gm radical hysterectomy specimen. The specimen is comprised of uterine corpus (5.0 cm in length by 4.3 x 4.0 cm), uterine cervix (3.5 x 3.0 x 2.5 cm), vaginal cuff (0.5 to 2.0 cm in length), left paracervical soft tissue (3.5 x 2.0 x 1.5 cm), and right paracervical soft tissue (3.5 x 2.0 x 1.2 cm). The paracervical soft tissues are inked. The uterine corpus is surfaced by pink-tan, glistening serosa. The uterine cervix is partially surfaced by pink-tan, glistening to finely granular ectocervical mucosa, and features a central 0.9 cm patent os. A discrete invasive mass is not identified. On palpation, no lymph nodes are palpated within the paracervical soft tissues. On sectioning, the endocervical canal is yellow-tan and granular. A gray-white granular lesion is present on cut surface that extends 1.2 cm deep (to within 0.4 cm of the inked margin). The triangular endometrium is pink-tan, focally shaggy, and lush, with an average thickness of 0.3 cm. Within the anterior aspect is a 1.5 x 1.0 x 0.4 cm, tan-pink, polypoid lesion. No areas of invasion are identified. The surrounding myometrium is pink tan and fibrous with an average thickness of 1.6 cm. Within the myometrium is a 0.9 cm well-circumscribed, firm, rubbery intramural nodule. It features a gray-white, whorled and bulging cut surface with no evidence of hemorrhage or necrosis. Representative sections are submitted in cassettes C1-17, labeled _____ designated as follows: 1, anterior vaginal cuff, en face; 2, posterior vaginal cuff, en face; 3, right paracervical soft tissues, perpendicular; 4, left paracervical soft tissues, perpendicular; 5-7, anterior endoectocervix; 8-10, posterior endoectocervix; 11, anterior lower uterine segment; 12, posterior lower uterine segment; 13-14, full thickness anterior endomyometrium; 15-16, full thickness posterior endomyometrium; 17, whorled nodule. Additionally, a yellow and a green cassette are submitted for genomics research, each labeled _____. D. Container D is additionally labeled "left external iliac lymph node," and contains a 4.0 x 3.0 x 1.5 cm aggregate of yellow-tan, fibrofatty soft tissue. On palpation, seven possible firm, fatty lymph nodes are identified, ranging from 0.5 up to 2.0 cm in greatest dimension. They are entirely submitted in cassettes D1-2,

[page 4 of 4]
labeled _____ designated _____ follows: D1, five whole possible lymph nodes; D2, two whole possible lymph nodes

F. Container E is additionally labeled "left obturator lymph node," and contains a 5.0 x 4.0 x 1.8 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, five possible firm, fatty lymph nodes ranging from 0.3 up to 3.3 cm in greatest dimension. They are entirely submitted in cassettes E1-5, labeled _____, designated as follows: E1, four whole possible lymph nodes; E2-5, one whole possible lymph node, quadrisected.

F. Container F is additionally labeled "#6," and contains a 2.7 x 2.5 x 1.5 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, four possible firm, fatty lymph nodes are identified ranging from 0.3 up to 0.9 cm in greatest dimension. They are entirely submitted in cassette F, labeled _____

G. Container G is additionally labeled "right external iliac," and contains a 3.5 x 2.5 x 1.5 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, three possible firm fatty lymph nodes are identified, ranging from 0.4 up to 1.5 cm in greatest dimension. They are entirely submitted in cassette G, labeled _____

H. Container H is additionally labeled "#8" and contains a 5.5 x 3.0 x 2.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, four possible firm fatty lymph nodes are identified, ranging from 0.1 up to 6.0 cm in greatest dimension. They are entirely submitted in cassettes H1-5, labeled _____ designated as follows: H1, three whole possible lymph nodes; H2-5, one whole possible lymph node, serially sectioned.

I. Container I is additionally labeled "#9" and contains a 2.8 x 2.0 x 0.5 cm aggregate of yellow-tan, fibrofatty soft tissue. On palpation, three possible firm, fatty lymph nodes are identified ranging from 0.7 up to 1.3 cm in greatest dimension. They are entirely submitted in cassette I, labeled _____

J. Container J is additionally labeled "#10," and contains a 23.0 x 4.3 x 0.9 cm, yellow-tan, finely lobulated soft tissue consistent with omentum. Sectioning reveals a yellow-tan, fibrofatty cut surface with no nodules or lesions. Representative sections are submitted in cassettes

Source: NCI Genomic Data Commons file ef277193-756a-4a85-92cb-9d2996e725fc (TCGA-FU-A3NI.3FD96F22-8669-4908-8DEC-9B9A82A8D5D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).